Gene-level copy-number profile of tumor specimen ALCH-B2AP-TTP1-A from ALCHEMIST case ALCH-B2AP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.2 years (21,261 days).
Specimen ALCH-B2AP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 124116c3-a365-4923-bbc6-e67e7373c652.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/f4a41e0f-14e6-4582-b054-b7eae4e5b8fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 224; copy number 1: 15,111; copy number 2: 40,403; copy number 3: 2,844; copy number 4: 312; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 172 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,644,547–12,693,020, 2 genes: AADACL4, AC244670.1.
- chr3:134,597,801–135,439,888, 6 genes: EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1.
- chr8:8,095,946–8,116,949, 2 genes: RPS3AP31, SNRPCP17.
- chr9:19,507,452–25,089,151, 89 genes (broad region; genes not listed).
- chr9:137,867,925–138,253,217, 8 genes (within-gene range 0–2): AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr12:111,034,165–111,350,554, 3 genes (within-gene range 0–1): CUX2, MIR6760, RNA5SP373.
- chr12:124,946,825–125,031,231, 3 genes: DHX37, BRI3BP, THRIL.
- chr15:25,176,832–25,257,027, 42 genes (within-gene range 0–1): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr19:9,126,012–9,236,076, 8 genes: OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P.
- chr19:14,941,489–15,022,990, 2 genes (within-gene range 0–1): OR7C2, SLC1A6.
- chr19:22,902,538–22,925,547, 2 genes: AC022145.1, AC022145.2.
- chr19:23,123,188–23,204,556, 4 genes (within-gene range 0–1): BNIP3P37, AC124856.1, SNX6P1, AC092329.2.
- chr22:18,883,502–18,884,682, 1 gene (within-gene range 0–2): AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,086,022–8,089,089, 2 genes, copy number 5: AC105233.2, MIR548I3.

Autosomal genes at a single copy (total copy number 1): 12,310. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
